Somatic mutation profile of tumor specimen 0D9MKR from CCDI case PBBJAY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,479 days).
Specimen 0D9MKR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bea6e6d-e5b7-42ad-a5bb-2e1b24f97c9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9MKS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e584d3-770e-48a5-ae55-6b09dc4e75ab

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PACSIN1 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 210/450 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs769598563; called by muse, mutect2, varscan2
- PTEN | c.499A>C p.T167P | Missense Mutation (SNP) | VAF 191/208 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as CD075529, COSV64288434, COSV64311397; called by muse, mutect2, varscan2
- RCL1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 216/636 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1394119805, COSV67754853; called by muse, mutect2, varscan2
- SLC28A3 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs202155610, COSV100883142; called by muse, mutect2, varscan2
- METTL16 | c.1654C>G p.R552G | Missense Mutation (SNP) | VAF 287/310 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- NBPF3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 64/720 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- RUFY1 | c.308C>A p.A103E | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- OSR2 | c.924G>A p.P308= | Silent (SNP) | VAF 188/278 reads (68%) | catalogued as rs1370814963; called by muse, mutect2, varscan2
- RETREG3 | c.483C>T p.F161= | Silent (SNP) | VAF 35/1504 reads (2%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- SPATA31C2 | n.811G>A | RNA (SNP) | VAF 336/883 reads (38%) | catalogued as rs780101352; called by muse, mutect2, varscan2
